Somatic mutation profile of tumor specimen TCGA-43-2578-01A (aliquot TCGA-43-2578-01A-01D-1522-08) from TCGA case TCGA-43-2578, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.5 years (21,747 days).
Specimen TCGA-43-2578-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69c527c4-a04a-495a-87e4-edc0ee6769dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-2578-11A (Solid Tissue Normal), aliquot TCGA-43-2578-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44514bdd-58fe-46f2-be16-a3115401cadb

The open-access MAF lists 347 somatic variants for this specimen: 258 protein-altering or splice-affecting, 77 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 222, Silent 77, Nonsense Mutation 12, Splice Site 10, Frame Shift Del 9, RNA 7, Splice Region 3, 5'Flank 2, Intron 2, Translation Start Site 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 124/267 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; called by muse, mutect2, varscan2
- TTR | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1254341785, COSV52701622, COSV99379470; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.001); catalogued as COSV52629089; called by muse, mutect2, varscan2
- ABCC1 | c.1964G>T p.R655M | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as COSV60687438; called by muse, mutect2, varscan2
- ABCG5 | c.968A>T p.Q323L | Missense Mutation (SNP) | VAF 262/563 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV53211352; called by muse, mutect2, varscan2
- ACCSL | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1300284216, COSV66581475; called by muse, varscan2
- ACP4 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); catalogued as rs1292620986, COSV54517215; called by muse, mutect2, varscan2
- ACSM4 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs749254594, COSV68068045; called by muse, mutect2, varscan2
- ADAMTS8 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV57294148; called by muse, mutect2, varscan2
- ADGRG4 | c.7237A>T p.R2413* | Nonsense Mutation (SNP) | VAF 10/147 reads (7%) | catalogued as COSV54958325; called by muse, mutect2
- ALG10B | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1218991576, COSV100439817, COSV58142197; called by muse, mutect2, varscan2
- ALPG | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54966486; called by muse, mutect2
- ANKRD30A | c.618C>A p.C206* (on ENST00000611781; = p.C150* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 84/230 reads (37%) | catalogued as COSV64612389; called by muse, mutect2, varscan2
- ANO10 | c.406A>T p.R136* | Nonsense Mutation (SNP) | VAF 33/79 reads (42%) | catalogued as COSV52732021; called by muse, mutect2, varscan2
- ANO5 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749374398, COSV100201748, COSV61086066; called by muse, mutect2, varscan2
- ARHGAP30 | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV63517039; called by muse, mutect2, varscan2
- ARRDC1 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58376295; called by muse, varscan2
- ASCC3 | c.4604G>T p.C1535F | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64976249; called by muse, mutect2
- ASTN1 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs781276168, COSV56071652; called by muse, mutect2, varscan2
- ASXL3 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52468544; called by muse, mutect2, varscan2
- ATAD2 | c.3031A>T p.K1011* | Nonsense Mutation (SNP) | VAF 50/225 reads (22%) | catalogued as COSV54881709; called by muse, mutect2, varscan2
- ATG2A | c.2017C>G p.L673V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV65967121; called by muse, mutect2, varscan2
- ATG2A | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV65967122, COSV65967328; called by muse, mutect2, varscan2
- ATP11C | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV59565952; called by muse, mutect2, varscan2
- BEST3 | c.1729A>T p.N577Y | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV58302161; called by muse, mutect2, varscan2
- BIRC7 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53901574; called by muse, varscan2
- BRI3BP | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.181); catalogued as rs769412405, COSV58296372; called by muse, mutect2, varscan2
- C1orf94 | c.637G>T p.A213S (on ENST00000488417 / NM_001134734.2; = p.A23S on NM_032884.5) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV64914301; called by muse, mutect2, varscan2
- C5AR2 | c.607A>G p.I203V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57256446; called by muse, mutect2, varscan2
- CACNA1A | c.3137C>A p.P1046H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV64193815, COSV64200248; called by muse, mutect2, varscan2
- CACNA1F | c.665-1G>T p.X222_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV59904960; called by muse, mutect2, varscan2
- CACNA1I | c.367T>G p.F123V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV60810651, COSV60820140; called by muse, mutect2, varscan2
- CCDC180 | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as rs1204130611, COSV63831266; called by muse, varscan2
- CCDC28B | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV52209095; called by muse, mutect2, varscan2
- CD40LG | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV65698638; called by muse, mutect2, varscan2
- CD86 | c.102G>T p.E34D (on ENST00000330540 / NM_175862.5; = p.E28D on NM_006889.4) | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.144); catalogued as COSV52607390; called by muse, mutect2, varscan2
- CFAP47 | c.5096C>A p.A1699E | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV57974378; called by muse, mutect2, varscan2
- CFAP61 | c.2322G>C p.Q774H | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs772984036, COSV55632757; called by muse, mutect2, varscan2
- COG6 | c.1037T>A p.V346D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV62996355; called by muse, mutect2, varscan2
- COL5A1 | c.2294del p.P765Lfs*39 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | catalogued as COSV100880059; called by mutect2, pindel, varscan2
- COL6A6 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV62027503; called by muse, mutect2, varscan2
- CSRNP3 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58779485; called by muse, mutect2, varscan2
- CTAGE1 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as COSV66943728; called by muse, mutect2, varscan2
- CTAGE6 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV101417841; called by mutect2, varscan2
- CUBN | c.8233G>C p.D2745H | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64717959; called by muse, mutect2, varscan2
- CYP7B1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.82); catalogued as COSV59583230, COSV59590216; called by muse, mutect2, varscan2
- DCAF12L1 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV64421975; called by muse, mutect2, varscan2
- DDI1 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56380873; called by muse, mutect2
- DLEC1 | c.515G>T p.S172I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV57300918; called by muse, mutect2, varscan2
- DNAJC10 | c.1989G>T p.W663C | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899189; called by muse, mutect2, varscan2
- DQX1 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101099103, COSV66353281; called by muse, mutect2, varscan2
- DUS3L | c.961C>G p.R321G | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57832190, COSV57833543; called by muse, mutect2, varscan2
- EPB41L3 | c.1507-2A>T p.X503_splice | Splice Site (SNP) | VAF 33/108 reads (31%) | catalogued as rs778279169, COSV59456507; called by muse, mutect2, varscan2
- EPHB3 | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV57804299, COSV57806631; called by muse, mutect2, varscan2
- EPHX4 | c.1075A>G p.R359G | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64889595; called by muse, mutect2, varscan2
- EPS15 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65542867, COSV65544492; called by muse, mutect2, varscan2
- ERCC6L | c.3578C>G p.A1193G | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); catalogued as COSV57820961; called by muse, mutect2, varscan2
- EYA4 | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM154547, COSV62058091; called by muse, mutect2, varscan2
- F10 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV65022061; called by muse, varscan2
- F9 | c.1255G>T p.V419L | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV54380772; called by muse, mutect2, varscan2
- FAM161B | c.278C>A p.A93E (on ENST00000651776; = p.A30E on NM_152445.3) | Missense Mutation (SNP) | VAF 161/299 reads (54%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.541); catalogued as COSV53179030, COSV53179849; called by muse, mutect2, varscan2
- FAM47B | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV61454463; called by muse, mutect2, varscan2
- FAM47C | c.1447G>T p.V483L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.784); catalogued as COSV63727228, COSV63729490; called by muse, mutect2, varscan2
- FAM47C | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.095); catalogued as COSV63724719, COSV63727234; called by muse, mutect2, varscan2
- FAM47C | c.2408C>T p.P803L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63727245; called by muse, mutect2, varscan2
- FANCB | c.2392G>T p.V798F | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.196); catalogued as COSV60760252; called by muse, mutect2, varscan2
- FAP | c.1952C>A p.S651Y | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51862741; called by muse, mutect2, varscan2
- FLNA | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV61044714; called by muse, varscan2
- FMOD | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 78/128 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV61610163; called by muse, mutect2, varscan2
- FMR1 | c.201G>T p.V67= | Splice Region (SNP) | VAF 71/387 reads (18%) | catalogued as COSV54424719; called by muse, mutect2, varscan2
- G6PD | c.22A>T p.S8C | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV54838640; called by muse, mutect2, varscan2
- GALNT5 | c.1495A>T p.S499C | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52038359; called by muse, mutect2, varscan2
- GCKR | c.1243A>C p.N415H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.754); catalogued as rs1282396032, COSV53108560; called by muse, mutect2, varscan2
- GDF10 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as rs1194938807; called by muse, mutect2, varscan2
- GHSR | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53839851; called by muse, mutect2, varscan2
- GIMAP5 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57530093; called by muse, mutect2, varscan2
- GJB4 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs80358212, CM035047, COSV100258328, COSV58356373; called by muse, mutect2, varscan2
- GLYATL1 | c.634G>T p.G212C (on ENST00000317391 / NM_001354699.1; = p.G243C on NM_080661.4) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100265293; called by muse, mutect2, varscan2
- GPATCH1 | c.1387A>T p.R463W | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV50116794; called by muse, mutect2, varscan2
- GPR162 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs782478623, COSV50591671; called by muse, mutect2, varscan2
- GPR34 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV59368103; called by muse, mutect2, varscan2
- GPRASP1 | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV64355800; called by muse, mutect2, varscan2
- GRM8 | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV100281891, COSV58832977; called by muse, mutect2, varscan2
- GUCY1A2 | c.900T>A p.N300K | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56489461, COSV99972307; called by muse, mutect2, varscan2
- H1-8 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.773); catalogued as COSV60974060; called by muse, mutect2, varscan2
- H4C3 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 88/140 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs748976885, COSV58090704; called by muse, mutect2, varscan2
- HEPH | c.2843C>G p.P948R (on ENST00000343002; = p.P681R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV100294524, COSV57960255, COSV57965431; called by muse, mutect2, varscan2
- HUWE1 | c.10595C>A p.T3532N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.051); catalogued as COSV53348713; called by muse, mutect2, varscan2
- IGKV1-12 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 69/640 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1359904035; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1331A>T p.Y444F | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV56269277; called by muse, mutect2, varscan2
- IQCG | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 171/609 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV54562816; called by muse, mutect2, varscan2
- IQGAP3 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV63252230; called by muse, varscan2
- IRS4 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.859); catalogued as COSV64534224; called by muse, varscan2
- ITGA2 | c.1487G>C p.C496S | Missense Mutation (SNP) | VAF 112/271 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV56860911; called by muse, mutect2, varscan2
- KAT2B | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV55430434; called by muse, mutect2, varscan2
- KCNJ3 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54537515; called by muse, mutect2, varscan2
- KCNMA1 | c.2361G>T p.R787S (on ENST00000286628 / NM_001161352.2; = p.R729S on NM_002247.4) | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.366); catalogued as COSV54230590, COSV99699178; called by muse, mutect2, varscan2
- KEAP1 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50262252, COSV50294540, COSV99407448; called by muse, mutect2, varscan2
- KIAA1109 | c.12407C>T p.S4136L | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV52677056; called by muse, mutect2, varscan2
- KMT2A | c.5745C>A p.D1915E | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as COSV63286831; called by muse, mutect2, varscan2
- KNCN | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as COSV99606287; called by muse, mutect2, varscan2
- KRTAP12-3 | c.120C>A p.C40* | Nonsense Mutation (SNP) | VAF 130/218 reads (60%) | catalogued as COSV59966169; called by muse, mutect2, varscan2
- KRTAP27-1 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as COSV67001129; called by muse, mutect2
- LAMA1 | c.5008+1G>A p.X1670_splice | Splice Site (SNP) | VAF 81/241 reads (34%) | catalogued as COSV67538673; called by muse, mutect2, varscan2
- LAMC3 | c.3290T>A p.L1097Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV63092264; called by muse, mutect2
- LAPTM5 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV99612367; called by muse, mutect2, varscan2
- LCE2B | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64227722; called by muse, mutect2, varscan2
- LDB2 | c.996C>A p.N332K | Missense Mutation (SNP) | VAF 120/264 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs748150349, COSV58771418; called by muse, varscan2
- LINGO2 | c.229T>C p.F77L | Missense Mutation (SNP) | VAF 148/422 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.274); catalogued as COSV58060488; called by muse, varscan2
- LPXN | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1245609473, COSV67717332; called by muse, mutect2, varscan2
- LSG1 | c.867G>C p.R289S | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54570776, COSV99503202; called by muse, mutect2, varscan2
- LZTR1 | c.1183G>T p.V395F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV53148144; called by muse, mutect2, varscan2
- MAGEC2 | c.311G>C p.C104S | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV55999672; called by muse, varscan2
- MAML2 | c.1495G>T p.G499W | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV73263749; called by muse, mutect2, varscan2
- MAP1LC3C | c.400A>T p.R134W | Missense Mutation (SNP) | VAF 95/162 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61803790; called by muse, mutect2, varscan2
- MB21D2 | c.902G>A p.C301Y | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.425); catalogued as COSV66663946, COSV66664278; called by muse, mutect2, varscan2
- MED23 | c.3869A>G p.Y1290C | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV63433175; called by muse, mutect2, varscan2
- MEGF11 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56545554; called by muse, mutect2, varscan2
- MEPE | c.556T>C p.Y186H | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.392); catalogued as rs768622509, COSV63073080; called by muse, varscan2
- MIA3 | c.2215G>T p.A739S | Missense Mutation (SNP) | VAF 100/170 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60513942; called by muse, mutect2, varscan2
- MICU2 | c.358+1G>C p.X120_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as COSV66674271; called by muse, mutect2, varscan2
- MKRN3 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58808648; called by muse, mutect2, varscan2
- MLH1 | c.1460G>T p.R487L | Missense Mutation (SNP) | VAF 153/316 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs587778917, COSV51619099, COSV51621609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP9 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV63434169; called by muse, varscan2
- MOGAT2 | c.209A>T p.H70L | Missense Mutation (SNP) | VAF 139/444 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV52220025; called by muse, mutect2, varscan2
- MS4A3 | c.625T>A p.S209T | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV53936479; called by muse, mutect2, varscan2
- MSR1 | c.1232C>A p.P411Q | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV50514527; called by muse, mutect2, varscan2
- MUC16 | c.12311C>G p.S4104* | Nonsense Mutation (SNP) | VAF 40/97 reads (41%) | catalogued as COSV67472336; called by muse, mutect2, varscan2
- MUC4 | c.15169-1G>T p.X5057_splice (on ENST00000463781 / NM_018406.7; = p.X821_splice on NM_004532.6) | Splice Site (SNP) | VAF 14/94 reads (15%) | catalogued as COSV57785053; called by muse, mutect2, varscan2
- MYH1 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV56850031; called by muse, mutect2, varscan2
- MYOM1 | c.4906G>A p.V1636M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773263720, COSV55293391; called by muse, mutect2, varscan2
- MYRF | c.941T>A p.I314N (on ENST00000278836 / NM_001127392.3; = p.I305N on NM_013279.4) | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.454); catalogued as COSV53889774; called by muse, mutect2, varscan2
- MYT1 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV60501110, COSV60507115; called by muse, varscan2
- NBR1 | c.2827A>T p.N943Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57833123; called by muse, mutect2
- NCK2 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51892129; called by muse, mutect2, varscan2
- NCOR1 | c.59A>T p.Y20F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51959192, COSV51978110; called by muse, mutect2, varscan2
- NCOR2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as rs1211294271, COSV62299249; called by mutect2, varscan2
- NETO2 | c.1561A>T p.I521L | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57453343; called by muse, mutect2, varscan2
- NEXMIF | c.4257C>A p.N1419K | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV50038217; called by muse, mutect2, varscan2
- NLGN1 | c.859+1G>T p.X287_splice | Splice Site (SNP) | VAF 67/155 reads (43%) | catalogued as COSV64336235; called by muse, mutect2, varscan2
- NLGN1 | c.2314G>T p.D772Y | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64336242; called by muse, mutect2, varscan2
- NLGN3 | c.1486C>A p.R496S (on ENST00000358741 / NM_181303.2; = p.R476S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV100704683; called by muse, mutect2
- NLGN3 | c.2519C>A p.P840H (on ENST00000358741 / NM_181303.2; = p.P820H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62443654; called by muse, mutect2, varscan2
- NUP133 | c.1584A>T p.Q528H | Missense Mutation (SNP) | VAF 99/156 reads (63%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54572262; called by muse, mutect2, varscan2
- OCRL | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); catalogued as COSV63980597; called by muse, mutect2, varscan2
- OLFM1 | c.183G>T p.Q61H (on ENST00000371793 / NM_001282611.2; = p.Q43H on NM_006334.4) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52962524; called by muse, mutect2, varscan2
- OOEP | c.231C>A p.S77R | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV64859302; called by muse, mutect2, varscan2
- OR2T33 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 145/290 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58815741; called by muse, varscan2
- OR2W1 | c.56A>G p.N19S | Missense Mutation (SNP) | VAF 68/307 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65851659; called by muse, mutect2, varscan2
- OR4C15 | c.943C>G p.P315A (on ENST00000314644; = p.P261A on NM_001001920.2) | Missense Mutation (SNP) | VAF 105/468 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.792); catalogued as COSV58952339, COSV58953315; called by muse, mutect2, varscan2
- OR4Q3 | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 99/177 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV59178933; called by muse, mutect2, varscan2
- OR51T1 | c.635A>T p.D212V | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59025870; called by muse, varscan2
- OR56A3 | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV61569291; called by muse, mutect2, varscan2
- OR5D14 | c.662T>A p.V221D | Missense Mutation (SNP) | VAF 124/364 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV59456740; called by muse, mutect2, varscan2
- OR7C2 | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV50180796; called by muse, mutect2, varscan2
- OR8D4 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58429485, COSV58430624; called by muse, mutect2, varscan2
- PCDH15 | c.4909T>A p.S1637T | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated, low confidence (0.37); catalogued as COSV64701065; called by muse, mutect2, varscan2
- PCDHGA3 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.05); catalogued as COSV53917549, COSV53964395; called by muse, mutect2, varscan2
- PGK1 | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV64832139; called by muse, mutect2, varscan2
- PIGT | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 115/349 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54126766; called by muse, mutect2, varscan2
- PIK3CG | c.777G>T p.M259I | Missense Mutation (SNP) | VAF 106/164 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV63247013, COSV63249282; called by muse, mutect2, varscan2
- PKHD1L1 | c.7937C>A p.A2646E | Missense Mutation (SNP) | VAF 150/588 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV65745005; called by muse, mutect2, varscan2
- PLXNA4 | c.1162G>T p.V388L | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV58132663; called by muse, varscan2
- PLXNA4 | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.625); catalogued as COSV58132706; called by muse, varscan2
- PNMA5 | c.692T>G p.L231R | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62625742; called by muse, mutect2, varscan2
- PNMA8B | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66536804; called by muse, mutect2, varscan2
- POP1 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 154/356 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV62893083; called by muse, mutect2, varscan2
- POU2F3 | c.769+2T>A p.X257_splice | Splice Site (SNP) | VAF 12/118 reads (10%) | catalogued as COSV52794624; called by muse, mutect2
- PRICKLE3 | c.954C>T p.I318= | Splice Region (SNP) | VAF 36/88 reads (41%) | catalogued as rs376833620, COSV66234151; called by muse, mutect2, varscan2
- PRKCB | c.269A>T p.D90V | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as rs750901145, COSV57783485; called by muse, mutect2, varscan2
- PRKDC | c.8024C>T p.S2675F | Missense Mutation (SNP) | VAF 129/446 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs369642176; called by muse, mutect2, varscan2
- PRR11 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 93/162 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51877072, COSV99231792; called by muse, mutect2, varscan2
- PSG7 | c.45G>C p.W15C | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV68445394; called by muse, mutect2, varscan2
- PTPN4 | c.1414A>G p.K472E | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.142); catalogued as COSV55302849; called by muse, mutect2, varscan2
- PTX3 | c.1087A>T p.I363F | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV55821758; called by muse, mutect2, varscan2
- RAB39B | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV101034968, COSV65624513; called by muse, mutect2
- RARS1 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as rs757507711, COSV51564056; called by muse, mutect2, varscan2
- RB1 | c.1901C>G p.S634* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as CM961233, COSV57296525, COSV57302654; called by muse, mutect2, varscan2
- RGS6 | c.1097G>T p.W366L | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59580080; called by muse, mutect2, varscan2
- RNF10 | c.151A>C p.K51Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV58044052, COSV58045919; called by muse, mutect2
- RNF181 | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 139/411 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57818061; called by muse, mutect2, varscan2
- RNF207 | c.1505G>C p.R502P | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV65007802; called by muse, varscan2
- ROR2 | c.2433G>A p.M811I | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as COSV65219953; called by muse, mutect2, varscan2
- RPGR | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100139914; called by mutect2, varscan2
- SALL1 | c.3494C>A p.T1165N | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV51758851; called by muse, mutect2, varscan2
- SCN10A | c.652A>T p.R218* | Nonsense Mutation (SNP) | VAF 82/181 reads (45%) | catalogued as COSV71861761; called by muse, mutect2, varscan2
- SEMG2 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs368513832; called by muse, mutect2, varscan2
- SFMBT2 | c.1214G>T p.S405I | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV62810916; called by muse, mutect2, varscan2
- SGIP1 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 72/369 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV52771012; called by muse, mutect2, varscan2
- SHC2 | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV52746746; called by muse, mutect2, varscan2
- SLAMF7 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.355); catalogued as rs753606290, COSV63563364; called by muse, mutect2, varscan2
- SLC24A4 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 16/166 reads (10%) | catalogued as COSV54114496; called by muse, mutect2
- SLC6A6 | c.1058A>G p.Q353R | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as COSV62650320; called by muse, mutect2, varscan2
- SLC9A2 | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV52132966; called by muse, mutect2, varscan2
- SLITRK3 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53849238; called by muse, mutect2, varscan2
- SMPD2 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.203); catalogued as COSV57805755; called by muse, mutect2, varscan2
- SOBP | c.171G>C p.E57D | Missense Mutation (SNP) | VAF 117/191 reads (61%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV57998898; called by muse, mutect2, varscan2
- SPATA21 | c.86C>G p.A29G | Missense Mutation (SNP) | VAF 129/383 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59187341; called by muse, mutect2, varscan2
- SPATA31E1 | c.2927T>C p.V976A | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.225); catalogued as COSV57790116, COSV57792526; called by mutect2, varscan2
- SPIC | c.176C>G p.T59R | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.203); catalogued as COSV54691660; called by muse, mutect2, varscan2
- SPRED3 | c.424-1G>T p.X142_splice | Splice Site (SNP) | VAF 10/21 reads (48%) | catalogued as COSV58312907; called by muse, mutect2, varscan2
- SSX1 | c.29G>T p.R10I | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV65355678; called by muse, mutect2
- ST7 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 107/292 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55386560; called by muse, mutect2, varscan2
- SYMPK | c.2490G>T p.P830= | Splice Region (SNP) | VAF 22/130 reads (17%) | catalogued as COSV55612589, COSV55615816; called by muse, mutect2, varscan2
- SYNE1 | c.11441G>T p.G3814V (on ENST00000367255 / NM_182961.4; = p.G3799V on NM_033071.3) | Missense Mutation (SNP) | VAF 248/621 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as COSV55005209; called by muse, mutect2, varscan2
- SYNE1 | c.4009-1G>T p.X1337_splice (on ENST00000367255 / NM_182961.4; = p.X1344_splice on NM_033071.3) | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as COSV55005240; called by muse, mutect2, varscan2
- TAF1 | c.1886T>C p.M629T (on ENST00000373790 / NM_138923.4; = p.M650T on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV52108129, COSV52115532; called by muse, mutect2, varscan2
- TAS2R19 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 130/491 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs770713225, COSV66828505; called by muse, varscan2
- TAS2R41 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV68765403; called by muse, mutect2, varscan2
- TCOF1 | c.1136A>T p.K379M (on ENST00000377797 / NM_001135243.1; = p.K302M on NM_000356.4) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60349541; called by muse, mutect2, varscan2
- TH | c.359G>T p.R120M (on ENST00000381178 / NM_199292.3; = p.R89M on NM_000360.4) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV60767570; called by muse, mutect2, varscan2
- TIE1 | c.1201A>T p.I401F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); catalogued as COSV65250001; called by muse, mutect2, varscan2
- TMEM161B | c.1402G>C p.A468P | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56931393; called by muse, mutect2, varscan2
- TMEM25 | c.229T>A p.S77T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV57097011; called by muse, mutect2, varscan2
- TRAPPC8 | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768476324, COSV51967302; called by muse, mutect2, varscan2
- TRIO | c.6750T>G p.I2250M | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV59990562; called by muse, mutect2, varscan2
- TRIOBP | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV60378984; called by muse, mutect2
- TRPS1 | c.1051G>T p.E351* (on ENST00000220888 / NM_001330599.2; = p.E364* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 157/363 reads (43%) | catalogued as CM1514912, COSV55244727; called by muse, mutect2, varscan2
- TRRAP | c.3004A>G p.I1002V | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs782451280, COSV62846302; called by muse, mutect2
- TSHZ2 | c.1522G>C p.D508H | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV61589307; called by muse, mutect2, varscan2
- TTN | c.71686C>T p.R23896C (on ENST00000591111; = p.R16472C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | PolyPhen probably damaging (0.982); catalogued as rs527631472, COSV60118046; called by muse, mutect2, varscan2
- TUT1 | c.2324G>A p.W775* | Nonsense Mutation (SNP) | VAF 51/161 reads (32%) | catalogued as COSV53470393; called by muse, mutect2, varscan2
- UBQLN2 | c.418A>T p.S140C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV57739753; called by muse, mutect2, varscan2
- UFL1 | c.1048A>T p.S350C | Missense Mutation (SNP) | VAF 84/131 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV65149991; called by muse, mutect2, varscan2
- UGT1A6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 44/184 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); catalogued as COSV59390521; called by muse, mutect2
- UGT2B11 | c.772A>C p.M258L | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV71423504; called by muse, mutect2
- UNC5C | c.764T>A p.V255D | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71660389; called by muse, mutect2, varscan2
- UNC5D | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 40/498 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54801415; called by muse, mutect2
- UPP1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as rs368798686, COSV57977755; called by muse, mutect2, varscan2
- USP24 | c.5615C>G p.T1872S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.824); catalogued as COSV53769612; called by muse, mutect2
- USP51 | c.2122C>A p.L708I | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as COSV72351723; called by muse, mutect2, varscan2
- VPS41 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV59649604; called by muse, mutect2, varscan2
- WDR64 | c.1255A>C p.M419L | Missense Mutation (SNP) | VAF 115/194 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV63796764; called by muse, mutect2, varscan2
- ZCRB1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56891670; called by muse, mutect2, varscan2
- ZFHX4 | c.1561G>A p.G521S | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.073); catalogued as rs763235796, COSV50998747; called by muse, mutect2, varscan2
- ZFR2 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1220831775, COSV53599595; called by muse, mutect2, varscan2
- ZNF136 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59710998; called by muse, mutect2, varscan2
- ZNF28 | c.1160A>T p.E387V | Missense Mutation (SNP) | VAF 107/309 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV60423524; called by muse, mutect2, varscan2
- ZNF362 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV65031502; called by muse, mutect2, varscan2
- ZNF41 | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57443311; called by muse, mutect2, varscan2
- ZNF423 | c.853G>A p.E285K (on ENST00000563137 / NM_001379286.1; = p.E277K on NM_015069.4) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as rs1313395769, COSV52191771; called by muse, mutect2, varscan2
- ZNF574 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs778036814, COSV55904215; called by muse, mutect2
- ZNF687 | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55018112; called by muse, mutect2, varscan2
- ZNF835 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs1392149504, COSV73379249; called by muse, mutect2, varscan2
- ZZZ3 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV66233443; called by muse, mutect2, varscan2
- AHNAK2 | c.1881_1890del p.R628Kfs*3 | Frame Shift Del (DEL) | VAF 300/890 reads (34%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.1813del p.A605Hfs*31 (on ENST00000392017 / NM_030803.7; = p.A586Hfs*31 on NM_017974.4) | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- CSMD3 | c.9042del p.S3015Lfs*14 (on ENST00000297405 / NM_001363185.1; = p.S2846Lfs*14 on NM_052900.3) | Frame Shift Del (DEL) | VAF 71/214 reads (33%) | called by mutect2, pindel, varscan2
- HTR1A | c.883del p.V295Cfs*50 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.44C>G p.T15R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- IGHV3-66 | c.92T>G p.I31S | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); called by mutect2, varscan2
- KMT2D | c.7839_7853del p.S2614_P2618del | In Frame Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- MELTF | c.254_258del p.A85Efs*36 | Frame Shift Del (DEL) | VAF 36/169 reads (21%) | called by mutect2, pindel, varscan2
- MSMB | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, varscan2
- MXRA5 | c.2802del p.T935Pfs*59 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1487-7_1508del p.X496_splice | Splice Site (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel
- TENM1 | c.5182_5188del p.V1728Lfs*60 | Frame Shift Del (DEL) | VAF 21/165 reads (13%) | called by mutect2, pindel, varscan2
- TRIM41 | c.488_513del p.E163Afs*155 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- AARD | c.147C>T p.A49= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1186116583, COSV65600033; called by muse, mutect2, varscan2
- ABCA4 | c.6648G>A p.A2216= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs779465743, COSV64674270; called by muse, mutect2, varscan2
- ACSM1 | c.72T>A p.P24= | Silent (SNP) | VAF 104/376 reads (28%) | catalogued as COSV54636599; called by muse, varscan2
- AMER1 | c.1269G>T p.L423= | Silent (SNP) | VAF 40/193 reads (21%) | catalogued as COSV57659057; called by muse, mutect2, varscan2
- ARID1B | c.4212G>A p.R1404= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as rs770732982, COSV51665243; called by muse, mutect2, varscan2
- ATP9A | c.1329G>T p.T443= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV100125283, COSV58767685; called by muse, mutect2, varscan2
- BACE2 | c.1534C>T p.L512= | Silent (SNP) | VAF 62/192 reads (32%) | catalogued as COSV57740295; called by muse, mutect2, varscan2
- BCL6B | c.433C>T p.L145= | Silent (SNP) | VAF 54/185 reads (29%) | catalogued as COSV53428189; called by muse, mutect2, varscan2
- CASS4 | c.2289G>T p.A763= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs772143299, COSV64386784, COSV64387957; called by muse, mutect2, varscan2
- CCNB3 | c.711A>C p.A237= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as COSV52074756; called by muse, mutect2, varscan2
- CDC42BPB | c.3663G>T p.L1221= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as COSV63475361; called by muse, mutect2, varscan2
- CTAGE1 | c.1302G>T p.S434= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as COSV101194516, COSV66945004; called by muse, mutect2, varscan2
- CUL2 | c.513T>G p.R171= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV66079465; called by muse, mutect2, varscan2
- CYP7B1 | c.1185C>A p.I395= | Silent (SNP) | VAF 56/207 reads (27%) | catalogued as COSV59590205; called by muse, varscan2
- DHCR7 | c.297C>G p.L99= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV62795614; called by mutect2, varscan2
- DHX58 | c.753G>T p.R251= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV52426305; called by muse, mutect2, varscan2
- DIAPH2 | c.2697A>G p.E899= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV61273296; called by muse, mutect2, varscan2
- DNAH3 | c.5979C>A p.P1993= | Silent (SNP) | VAF 68/250 reads (27%) | catalogued as COSV54527378; called by muse, mutect2, varscan2
- EBF3 | c.468C>G p.T156= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV62475999; called by muse, mutect2
- EBF3 | c.162C>T p.F54= | Silent (SNP) | VAF 40/59 reads (68%) | catalogued as COSV62476004; called by muse, mutect2, varscan2
- ECSIT | c.195C>G p.P65= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV52939700; called by muse, mutect2, varscan2
- EIF1AD | c.138G>A p.G46= | Silent (SNP) | VAF 58/160 reads (36%) | catalogued as COSV56463740; called by muse, mutect2, varscan2
- ELF3 | c.993G>A p.R331= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV62837538, COSV62838684; called by muse, mutect2, varscan2
- ENKD1 | c.111G>A p.A37= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV54676390; called by muse, mutect2
- EPHA4 | c.792T>A p.A264= | Silent (SNP) | VAF 49/164 reads (30%) | catalogued as COSV56035388; called by muse, mutect2, varscan2
- F11R | c.21C>G p.V7= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV57038057; called by muse, mutect2, varscan2
- FAM47A | c.513G>A p.K171= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV60497487; called by muse, mutect2, varscan2
- FAM83C | c.2040G>T p.L680= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV65583365; called by muse, mutect2, varscan2
- FOXN3 | c.261C>A p.V87= | Silent (SNP) | VAF 54/153 reads (35%) | catalogued as COSV54310513; called by muse, mutect2, varscan2
- GDF10 | c.546C>G p.A182= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- HCN1 | c.1206T>C p.S402= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV57515934; called by muse, mutect2, varscan2
- HSPG2 | c.10026G>A p.R3342= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs552439702, COSV65933329; called by muse, mutect2, varscan2
- IGSF9B | c.2394C>T p.D798= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs376960993; called by muse, mutect2, varscan2
- IVD | c.411C>T p.I137= (on ENST00000651168; = p.I134= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs1357609658, COSV51099484; called by muse, mutect2, varscan2
- KLHL40 | c.939C>G p.G313= | Silent (SNP) | VAF 71/177 reads (40%) | catalogued as COSV55134926; called by muse, mutect2, varscan2
- LRRC10 | c.735A>G p.P245= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV64060448; called by muse, mutect2, varscan2
- LZTR1 | c.1182T>C p.A394= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV53148134; called by muse, mutect2, varscan2
- MAGEB1 | c.495G>A p.L165= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV66775881; called by muse, mutect2, varscan2
- MAGEC1 | c.1107C>A p.P369= | Silent (SNP) | VAF 61/430 reads (14%) | catalogued as COSV99595557; called by muse, mutect2, varscan2
- MCM6 | c.1110G>T p.L370= | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as COSV51466087, COSV51466952; called by muse, mutect2, varscan2
- MYH6 | c.588C>A p.A196= | Silent (SNP) | VAF 67/111 reads (60%) | catalogued as COSV62451581; called by muse, mutect2, varscan2
- NLRP12 | c.1197C>A p.T399= | Silent (SNP) | VAF 121/351 reads (34%) | catalogued as COSV100145197; called by mutect2, varscan2
- NMNAT3 | c.234C>A p.I78= (on ENST00000296202 / NM_001320512.1; = p.I41= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV56156780, COSV56159911; called by muse, mutect2, varscan2
- NOBOX | c.900T>C p.D300= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as COSV56195103; called by muse, mutect2, varscan2
- NOMO1 | c.813G>T p.T271= | Silent (SNP) | VAF 116/534 reads (22%) | catalogued as rs758903904, COSV99814486; called by muse, mutect2, varscan2
- NOX3 | c.519A>C p.A173= | Silent (SNP) | VAF 77/206 reads (37%) | catalogued as COSV50153964; called by muse, mutect2, varscan2
- NPC1L1 | c.2521C>T p.L841= | Silent (SNP) | VAF 61/115 reads (53%) | catalogued as COSV56926101; called by muse, mutect2, varscan2
- NRAP | c.507C>T p.S169= | Silent (SNP) | VAF 44/228 reads (19%) | catalogued as rs138386465, COSV63491315; called by muse, varscan2
- NVL | c.1590G>A p.R530= | Silent (SNP) | VAF 75/131 reads (57%) | catalogued as COSV55873071; called by muse, mutect2, varscan2
- OR8K5 | c.138C>T p.I46= | Silent (SNP) | VAF 77/252 reads (31%) | catalogued as COSV100537154, COSV57889393; called by muse, mutect2, varscan2
- PHLDB2 | c.2484A>G p.K828= (on ENST00000393925 / NM_001134439.2; = p.K785= on NM_145753.2) | Silent (SNP) | VAF 71/172 reads (41%) | catalogued as COSV67312269; called by muse, varscan2
- PNMA8A | c.1254T>G p.S418= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as COSV58137407; called by muse, mutect2, varscan2
- PPP1R9A | c.696G>T p.G232= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as COSV56896328; called by muse, mutect2, varscan2
- PRAF2 | c.168C>G p.L56= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV59876210, COSV59876306; called by muse, mutect2, varscan2
- PSKH2 | c.120C>A p.A40= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV52610931; called by muse, mutect2, varscan2
- RBM42 | c.336C>T p.P112= | Silent (SNP) | VAF 92/246 reads (37%) | catalogued as rs1049663709, COSV52897882; called by muse, mutect2, varscan2
- RGL3 | c.1662G>A p.G554= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as COSV66509325; called by muse, mutect2, varscan2
- RTL8B | c.66C>T p.R22= | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as COSV66954329; called by muse, mutect2, varscan2
- SCG3 | c.843T>C p.Y281= | Silent (SNP) | VAF 80/173 reads (46%) | catalogued as COSV55021626; called by muse, mutect2, varscan2
- SCN10A | c.1164G>T p.L388= | Silent (SNP) | VAF 77/185 reads (42%) | catalogued as COSV71861760; called by muse, mutect2, varscan2
- SLC10A3 | c.1374C>A p.S458= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99682094; called by mutect2, varscan2
- SLC7A9 | c.924T>C p.F308= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV50086632; called by muse, mutect2, varscan2
- SPPL3 | c.537C>T p.A179= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs773557756, COSV62232803; called by muse, mutect2, varscan2
- SSX3 | c.495C>A p.T165= | Silent (SNP) | VAF 98/641 reads (15%) | catalogued as rs782149886, COSV53644395; called by muse, mutect2, varscan2
- SUOX | c.1014G>C p.R338= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV56268952; called by muse, mutect2, varscan2
- TAF7L | c.201G>C p.A67= | Silent (SNP) | VAF 96/276 reads (35%) | catalogued as rs748167428, COSV100774185, COSV100774244; called by mutect2, varscan2
- TECTA | c.4287C>A p.S1429= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV50695075, COSV50720911; called by muse, mutect2
- TMEM132E | c.2391G>T p.L797= (on ENST00000321639; = p.L887= on NM_001304438.2) | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV58697828; called by muse, mutect2, varscan2
- TMX4 | c.705T>A p.A235= | Silent (SNP) | VAF 65/197 reads (33%) | catalogued as COSV55680984; called by muse, mutect2, varscan2
- VIT | c.1863G>C p.V621= (on ENST00000389975 / NM_001177969.1; = p.V636= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV64897012; called by muse, mutect2, varscan2
- VRTN | c.1812C>T p.S604= | Silent (SNP) | VAF 51/81 reads (63%) | catalogued as COSV56441564; called by muse, mutect2, varscan2
- XKRX | c.963C>A p.G321= | Silent (SNP) | VAF 73/402 reads (18%) | catalogued as COSV60708348; called by muse, mutect2, varscan2
- ZMYM3 | c.144T>A p.P48= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1367236760, COSV58738386; called by muse, mutect2, varscan2
- ZNF20 | c.1080A>G p.T360= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as COSV61999628; called by muse, mutect2, varscan2
- ZNF254 | c.906A>G p.A302= | Silent (SNP) | VAF 40/74 reads (54%) | catalogued as COSV61642990; called by muse, mutect2, varscan2
- ZNF28 | c.1671G>A p.E557= | Silent (SNP) | VAF 93/252 reads (37%) | catalogued as COSV60423517, COSV60425750; called by muse, mutect2, varscan2
- ZNFX1 | c.1455C>T p.C485= | Silent (SNP) | VAF 20/307 reads (7%) | catalogued as rs768769964, COSV65575993; called by muse, mutect2
- C14orf177 | n.683T>A | RNA (SNP) | VAF 102/188 reads (54%) | catalogued as COSV57901086; called by muse, mutect2, varscan2
- CACNA1C | c.1481+555G>T | Intron (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100216354; called by muse, mutect2, varscan2
- CDH11 | c.1895-591C>G | Intron (SNP) | VAF 15/29 reads (52%) | catalogued as rs747561850, COSV99218150; called by muse, mutect2, varscan2
- DEPDC5 | c.*956G>T | 3'UTR (SNP) | VAF 105/217 reads (48%) | catalogued as COSV56699834; called by muse, mutect2, varscan2
- FOLH1B | n.1928A>T | RNA (SNP) | VAF 63/176 reads (36%) | called by muse, mutect2, varscan2
- MAT2B | chr5:163503398 C>T | 5'Flank (SNP) | VAF 45/143 reads (31%) | catalogued as COSV99796646; called by muse, mutect2, varscan2
- MATK | chr19:3789341 C>A | 5'Flank (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100036039; called by muse, mutect2, varscan2
- MIR516A1 | n.77G>C | RNA (SNP) | VAF 109/197 reads (55%) | catalogued as rs1047731138; called by muse, mutect2, varscan2
- MIR518A2 | n.27A>T | RNA (SNP) | VAF 124/214 reads (58%) | called by muse, varscan2
- MIR888 | n.71A>T | RNA (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- SLC35E2A | n.1062G>T | RNA (SNP) | VAF 15/84 reads (18%) | catalogued as COSV55803795; called by muse, mutect2, varscan2
- UBTFL2 | n.354G>C | RNA (SNP) | VAF 29/90 reads (32%) | catalogued as rs1351673887; called by muse, mutect2, varscan2
